Somatic mutation profile of tumor specimen TCGA-N5-A4RA-01A (aliquot TCGA-N5-A4RA-01A-11D-A28R-08) from TCGA case TCGA-N5-A4RA, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC2; Age at diagnosis: 64.0 years (23,359 days).
Specimen TCGA-N5-A4RA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13dc82c3-88a0-48b5-80e8-b375a24d5ad8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RA-10A (Blood Derived Normal), aliquot TCGA-N5-A4RA-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3af06f65-737e-4bb5-ab39-680c954c9b1d

The open-access MAF lists 42 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, Frame Shift Del 3, Splice Region 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT12 | c.1518C>A p.I506= | Splice Region (SNP) | VAF 16/43 reads (37%) | catalogued as COSV56894980; called by muse, mutect2, varscan2
- ATG4A | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs370004662, COSV58965922; called by muse, mutect2, varscan2
- CLCN2 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55599877; called by muse, mutect2, varscan2
- DDX56 | c.1285C>A p.R429S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51836906; called by muse, mutect2, varscan2
- FBXW7 | c.1187G>A p.S396N (on ENST00000281708 / NM_001349798.2; = p.S316N on NM_018315.5) | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55904695; called by muse, mutect2, varscan2
- KRT6C | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 109/141 reads (77%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs370835586; called by muse, mutect2, varscan2
- MAP3K20 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.412); catalogued as COSV59106554; called by muse, mutect2, varscan2
- MAPKBP1 | c.1850C>T p.T617M (on ENST00000456763 / NM_001128608.2; = p.T611M on NM_014994.3) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs375353103; called by muse, mutect2, varscan2
- MTREX | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1200704701; called by muse, mutect2
- PIK3CG | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs1462095883, COSV63248897; called by muse, mutect2, varscan2
- PLXNB2 | c.4871G>A p.R1624Q | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100834082, COSV100834224, COSV63783405; called by muse, mutect2, varscan2
- SEPTIN5 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs745550752, COSV100820411; called by muse, mutect2, varscan2
- SULF1 | c.2273C>G p.P758R | Missense Mutation (SNP) | VAF 70/1684 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52693165; called by muse, mutect2
- TNPO3 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as rs150330408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPTE | c.523G>A p.V175I (on ENST00000618007 / NM_199261.4; = p.V157I on NM_199259.4) | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs755683317; called by muse, varscan2
- TRPM2 | c.3574C>T p.H1192Y | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1192242091; called by muse, mutect2
- TSEN2 | c.92A>G p.H31R | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs568361511; called by muse, mutect2, varscan2
- ZNF254 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.316); catalogued as rs1257383488, COSV61643082; called by muse, mutect2, varscan2
- ACOT2 | c.481C>G p.R161G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ARID4A | c.638T>G p.V213G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CD86 | c.663A>C p.E221D (on ENST00000330540 / NM_175862.5; = p.E215D on NM_006889.4) | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- CFAP47 | c.2506G>A p.G836R | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DAAM1 | c.1252A>T p.K418* | Nonsense Mutation (SNP) | VAF 50/97 reads (52%) | called by muse, mutect2, varscan2
- ITSN2 | c.3990G>A p.K1330= | Splice Region (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- LAMC1 | c.155_168del p.P52Rfs*88 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- MTSS1 | c.197C>A p.T66N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- NLRC3 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- PODXL2 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRH1 | c.5T>C p.L2P | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SMYD1 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53 | c.78del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 51/83 reads (61%) | called by mutect2, pindel, varscan2
- TRPC4 | c.1459T>G p.F487V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- WDR7 | c.1687A>G p.I563V | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZBTB7B | c.631del p.T211Pfs*9 (on ENST00000292176; = p.T245Pfs*9 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 102/334 reads (31%) | called by mutect2, pindel, varscan2
- ZMIZ1 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ARFGEF3 | c.1704G>T p.T568= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- FOCAD | c.1999C>T p.L667= | Silent (SNP) | VAF 69/77 reads (90%) | catalogued as rs374337191; called by muse, mutect2, varscan2
- HOXD12 | c.174C>T p.C58= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs894260752; called by muse, mutect2
- HSPB7 | c.393C>T p.D131= | Silent (SNP) | VAF 78/131 reads (60%) | catalogued as rs763032522; called by muse, mutect2, varscan2
- SCN1A | c.804G>A p.L268= | Silent (SNP) | VAF 29/113 reads (26%) | called by muse, mutect2, varscan2
- USH2A | c.180C>T p.L60= | Silent (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163081 G>C | 5'Flank (SNP) | VAF 20/200 reads (10%) | called by muse, mutect2, varscan2
